Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A4A8, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A4A8-01A (Primary Tumor).

[page 1 of 5]
Tel:

Fax:

Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-0-3

carcinoma, Squamous cell, NOS 8070/3

Site: esophagus, middle third C15.4

10/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	Vietnamese	
☒ Male ☐ Female	68 kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			121/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Trouble Swallowing; vocal change
Symptoms: Tired of eating
Clinical Findings:
Performance Scale (Karnofsky Score):
☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO		2 drinks/day	(yrs)	3 months ago (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found in the oesophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Esophageal Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: IIA		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of the oesophagus			
Primary Tumor			
Organ	Detailed Location	Size	
Oesophagus tumor	Middle third	2.5 x 2 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T2 N0 M0 Stage: II			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _

_ Date

ime

Preserved by: _

_ Date

ime

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
2	2	2	2			2	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Oesophageal Tumor	2.5 x 2 x 1 cm	Middle third	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: II A	
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			☒	Streaming			
Mosaic		☒		Storiform			
Necrosis		☒	☒	Fibrosis			
Lymphocytic Infiltration		☒		Palisading			
Vascular Invasion			☒	Cystic Degeneration			
Clusterized		☒		Bleeding			
Alveolar Formation			☒	Myxoid Change			
Indian File			☒	Psmmoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	☒		Glandular cell			Round Cell			Large Cell		
Spindle Cell	☒		Cell Stratification			Fibroblast			Small Cell		
Keratin	☒		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	☒		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl		☒	Gland formation			Myoblast			Plasma Cell		
Otherwise Specified: D1 75% D2 75%											

2. Cellular Differentiation:

Well	Moderately	Poor
	☒	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	
Nuclear Grade			☒	

Histological Diagnosis: Squamous cell carcinoma, 0-2

Comments: _____

Director, Research Pathology

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

HIF-AA Discrepancy		☒

8/29/12

Source: NCI Genomic Data Commons file 0cc58d8c-1849-48b0-a41a-b6eb82a3b86e (TCGA-LN-A4A8.60FF0C39-8A92-44AF-BF52-841368174119.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).